Surgical pathology report (de-identified scan), TCGA case TCGA-BI-A20A, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-BI-A20A-01A (Primary Tumor).

ICD-0-3
Carcinoma, Squamous cell, NOS 8090/3
Site: Cervix, NOS C53.9 for 4/7/11

PATIENT HISTORY:

CHIEF COMPLAINT/ PRE-OP/ POST-OP DIAGNOSIS: Cervical cancer.

LMP DATE:

PROCEDURE: Radical hysterectomy, liver biopsy, pelvic and periaortic lymph node dissection.

SPECIFIC CLINICAL QUESTION: Not provided.

OUTSIDE TISSUE DIAGNOSIS: Not provided.

PRIOR MALIGNANCY: Not provided.

CHEMORADIATION THERAPY: Not provided.

OTHER DISEASES: Not provided.

FINAL DIAGNOSIS:

PART 1: LYMPH NODES, RIGHT, PELVIC, EXCISION -

THREE LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/3).

PART 2: LYMPH NODES, LEFT, PELVIC, EXCISION -

TWO LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/2).

PART 3: LYMPH NODE, LEFT, COMMON ILIAC, EXCISION -

ONE LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA (0/1).

PART 4: LYMPH NODE, RIGHT, PERIAORTIC, EXCISION -

ONE LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA (0/1).

PART 5: UTERUS, CERVIX, BILATERAL ADNEXA, RADICAL HYSTERECTOMY -

A. INVASIVE SQUAMOUS CELL CARCINOMA OF THE UTERINE CERVIX.

B. HISTOLOGIC GRADE: MODERATE TO POORLY DIFFERENTIATED.

C. THE TUMOR SIZE IS 2.0 X 2.0 CM.

D. THE TUMOR INVADES MORE THAN 90% OF THE CERVICAL STROMAL THICKNESS (0.6 CM INVASION OF 0.65-CM THICK CERVICAL STROMA).

E. NO EVIDENCE OF TUMOR MULTICENTRICITY IS IDENTIFIED.

F. IN-SITU CARCINOMA IS ALSO PRESENT.

G. LYMPHOVASCULAR SPACE INVASION IS PRESENT.

H. NO VAGINAL EXTENSION IS IDENTIFIED.

I. THE TUMOR EXTENDS PREDOMINANTLY INTO THE LOWER UTERINE SEGMENT MUCOSA AND FOCALLY IN THE STROMA.

J. ALL SURGICAL MARGINS ARE FREE OF TUMOR.

K. THE ENDOMETRIUM IS WEAKLY PROLIFERATIVE.

L. THE MYOMETRIUM IS UNREMARKABLE.

M. THE RIGHT OVARY SHOWS A BENIGN SEROUS CYST.

N. THE LEFT OVARY SHOWS EPITHELIAL INCLUSION GLANDS AND PHYSIOLOGICAL CHANGES.

O. BILATERAL BENIGN FALLOPIAN TUBES WITH PARATUBAL CYSTS.

P. A FEW PARAMETRIAL VESSELS WITH THROMBUS, CALCIFICATIONS AND RECANALIZATION.

Q. ONE LYMPH NODE IN THE RIGHT PARAMETRIAL TISSUE, NEGATIVE FOR METASTATIC CARCINOMA (0/1).

PART 6: LIVER, BIOPSY -

LIVER CORE NEGATIVE FOR METASTATIC CARCINOMA (see comment).

COMMENT:

The liver biopsy will also be sent to

-Hepatopathology for consultation. Their findings will be subsequently reported.

A companion pelvic wash is currently being processed and the results will be subsequently reported ("_____")

CASE SYNOPSIS:

SYNOPTIC - PRIMARY UTERINE CERVIX TUMORS: HYSTERECTOMY AND CONIZATION

TUMOR TYPE:

Squamous cell carcinoma

HISTOLOGIC GRADE:

Poorly differentiated

TUMOR SIZE:

High grade squamous intraepithelial lesion (HSIL)

TUMOR LOCATION:

Maximum dimension: 20 mm

DEPTH OF INVASION:

Ectocervix, Endocervix, Lower uterine segment

MARGINS OF RESECTION:

Greater than 2/3 of cervical thickness

Vaginal margin is negative for tumor

Parametrium margin is negative for tumor

MITOTIC RATE:

ANGIOLYMPHATIC INVASION:

Angiolymphatic invasion present

LYMPH NODES POSITIVE:

Number of lymph nodes positive: 0

LYMPH NODES EXAMINED:

Total number of lymph nodes examined: 8

T STAGE, PATHOLOGIC:

pT1b1

N STAGE, PATHOLOGIC:

pN0

M STAGE, PATHOLOGIC:

Not applicable

FIGO STAGE:

IB1

RESIDUAL TUMOR:

Rx

Source: NCI Genomic Data Commons file 753b6b13-6aec-40ae-a426-e57b4f9767df (TCGA-BI-A20A.FA32D74F-9855-489A-8217-F588682F96CE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).